Gene-level copy-number profile of tumor specimen TCGA-G4-6320-01A from TCGA case TCGA-G4-6320, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Hepatic flexure of colon; AJCC pathologic stage: Stage III; Age at diagnosis: 73.5 years (26,840 days).
Specimen TCGA-G4-6320-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.78321897-ac93-43ed-82c0-26c1f472e9f1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G4-6320-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/09e87dea-7f30-4fde-8679-aaa4c6d1fcd5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 4,388; copy number 2: 44,435; copy number 3: 5,641; copy number 4: 5; copy number 5: 926; copy number 6: 4,405.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G4-6320-01A-11D-1717-01): tumor purity 0.44, ploidy 2.29, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:59,747,277–61,251,459, 8 genes (within-gene range 0–2): FHIT, AC093418.1, AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,331 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–159,233,377, 3,014 genes, copy number 6 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 6 (broad region; genes not listed).
- chr20:25,985,210–26,086,917, 1 gene, copy number 5 (within-gene range 1–5): FAM182A.
- chr20:26,071,988–64,313,132, 925 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,354. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
